CPTAC case C3L-05362 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/552fdf86-691a-4c08-b917-e0bae420c008

Demographics
Sex at birth: female; Race: white; Year of birth: 1951; Vital status: Alive; Country of birth: Serbia.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 67.9 years (24,806 days); Year of diagnosis: 2019; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T3b; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,365 days (3.7 years); Progression or recurrence: yes; Days to last follow up: 1,365 days (3.7 years); Clark level: IV; Tumor focality: Unifocal; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >2.0-4.0 mm; Greatest tumor dimension: 1.3 cm; Lymph node involvement: Positive; Lymph nodes positive: 5; Lymph nodes tested: 18; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (4 entries)
- Days to follow up: 411 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 825 days (2.3 years); Disease response: Tumor Free.
- Days to follow up: 1,049 days (2.9 years); Disease response: Tumor Free; Karnofsky performance status: 100.
- Days to follow up: 1,365 days (3.7 years); Disease response: With Tumor; Karnofsky performance status: 100; ECOG performance status: 0.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-05362-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -13 days; Initial weight: 322 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-05362-22: Section location: Lymph node; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-05362-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -13 days; Initial weight: 428 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-05362-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -13 days; Method of sample procurement: Blood Draw.
